Somatic mutation profile of tumor specimen TCGA-D1-A17R-01A (aliquot TCGA-D1-A17R-01A-11D-A12J-09) from TCGA case TCGA-D1-A17R, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 58.5 years (21,382 days).
Specimen TCGA-D1-A17R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 886f22fc-df4d-4695-bb7e-c9c1104b56c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A17R-10A (Blood Derived Normal), aliquot TCGA-D1-A17R-10A-01D-A12J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db8d1d39-6381-42e6-a7ca-394562a3e429

The open-access MAF lists 276 somatic variants for this specimen: 222 protein-altering or splice-affecting, 51 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 156, Silent 51, Frame Shift Del 34, Nonsense Mutation 14, Frame Shift Ins 8, Splice Site 7, Splice Region 2, Intron 2, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1B | c.3880C>T p.Q1294* | Nonsense Mutation (SNP) | VAF 15/114 reads (13%) | catalogued as rs387907140, CM121890, COSV51647879; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CHD2 | c.4173del p.K1391Nfs*15 | Frame Shift Del (DEL) | VAF 42/244 reads (17%) | catalogued as rs749969667; ClinVar: uncertain significance / not provided / pathogenic; called by mutect2, varscan2
- COL18A1 | c.3918del p.G1307Dfs*17 (on ENST00000359759 / NM_130444.3; = p.G1072Dfs*17 on NM_030582.4) | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | catalogued as rs749009747; ClinVar: likely pathogenic / pathogenic; called by pindel, varscan2
- CTCF | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 5/70 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs968244943, COSV50461455; ClinVar: uncertain significance; called by muse, mutect2
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 43/118 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MYO3A | c.2180dup p.N727Kfs*9 | Frame Shift Ins (INS) | VAF 66/168 reads (39%) | catalogued as rs769462859; ClinVar: likely pathogenic; called by mutect2, varscan2
- PTEN | c.210-1G>A p.X70_splice | Splice Site (SNP) | VAF 77/201 reads (38%) | hotspot (GDC flag); catalogued as rs1114167621, CS002683, COSV64288901, COSV64300623, COSV64300922; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SERPINA1 | c.1158dup p.E387Rfs*14 | Frame Shift Ins (INS) | VAF 40/178 reads (22%) | catalogued as rs764325655; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- SIN3A | c.3310C>T p.R1104* | Nonsense Mutation (SNP) | VAF 28/172 reads (16%) | catalogued as rs879255621, COSV64581642; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.5342G>A p.G1781D | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV66063519; called by muse, mutect2
- ABCA3 | c.1303C>T p.R435* | Nonsense Mutation (SNP) | VAF 10/63 reads (16%) | catalogued as rs750071923, COSV57049244; called by muse, mutect2, varscan2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 26/72 reads (36%) | catalogued as rs749943218; called by mutect2, varscan2
- AC126283.2 | c.111del p.K37Nfs*65 | Frame Shift Del (DEL) | VAF 39/310 reads (13%) | catalogued as rs1560546604; called by mutect2, pindel, varscan2
- ACTG1 | c.503G>C p.G168A | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV59509594; called by muse, mutect2, varscan2
- ADAM15 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs879301995, COSV55125072; called by muse, mutect2
- ADAM20 | c.709G>A p.V237I | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.009); catalogued as rs531350369, COSV56454006; called by muse, mutect2
- ADAMTS10 | c.1661C>T p.T554I | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV54351751; called by muse, mutect2, varscan2
- ADIPOR1 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as rs764226232, COSV61850810; called by muse, mutect2
- ADRA2A | c.520G>A p.V174I | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.121); catalogued as COSV54526748; called by muse, mutect2, varscan2
- AGXT2 | c.963A>G p.E321= | Splice Region (SNP) | VAF 17/147 reads (12%) | catalogued as rs1420087952, COSV51483719; called by muse, mutect2, varscan2
- AIFM3 | c.152C>T p.T51M | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.123); catalogued as rs373462664; called by muse, mutect2
- ALDOA | c.1117G>T p.E373* (on ENST00000642816 / NM_001243177.4; = p.E319* on NM_184041.5) | Nonsense Mutation (SNP) | VAF 10/22 reads (45%) | catalogued as COSV57631944; called by muse, mutect2, varscan2
- ARHGEF15 | c.36del p.T13Rfs*169 | Frame Shift Del (DEL) | VAF 10/94 reads (11%) | catalogued as rs1338358886; called by mutect2, pindel
- ARID1A | c.3514C>T p.Q1172* | Nonsense Mutation (SNP) | VAF 30/197 reads (15%) | catalogued as COSV61371253; called by muse, mutect2, varscan2
- ASB15 | c.1586A>G p.Q529R | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV51923594; called by muse, mutect2, varscan2
- ATAD2B | c.2381T>G p.F794C | Missense Mutation (SNP) | VAF 52/229 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV53194849, COSV53197650; called by muse, mutect2, varscan2
- ATXN7 | c.1430C>A p.P477Q | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as COSV55747880; called by muse, mutect2
- B4GALNT2 | c.1021C>T p.R341W | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs527317913, COSV55924537; called by muse, mutect2, varscan2
- BAD | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54185603; called by mutect2, varscan2
- BHMT | c.98T>C p.L33P | Missense Mutation (SNP) | VAF 32/466 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57153485; called by muse, mutect2
- BICRA | c.2810del p.P937Hfs*10 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | catalogued as rs755506199; called by mutect2, varscan2
- BMP10 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 69/119 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.094); catalogued as rs141935259; called by muse, mutect2, varscan2
- BOP1 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1056384755; called by muse, mutect2, varscan2
- C1orf87 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 31/730 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0.23); catalogued as COSV64595984; called by muse, mutect2
- CACNA1C | c.2054G>A p.R685Q | Missense Mutation (SNP) | VAF 46/263 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs1204791018, COSV59695596; called by muse, mutect2, varscan2
- CAPRIN2 | c.770T>A p.F257Y | Missense Mutation (SNP) | VAF 13/242 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV51830207, COSV99195528; called by muse, mutect2
- CASZ1 | c.4612G>A p.G1538S | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.999); catalogued as COSV65455857; called by muse, mutect2, varscan2
- CCNL2 | c.1132C>T p.R378* | Nonsense Mutation (SNP) | VAF 25/67 reads (37%) | catalogued as COSV68766084; called by muse, mutect2, varscan2
- CCNQ | c.313G>A p.G105S | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs782206940, COSV52343821; called by muse, mutect2, varscan2
- CD5L | c.892C>T p.R298W | Missense Mutation (SNP) | VAF 17/256 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.947); catalogued as rs758841015, COSV63821004; called by muse, mutect2
- CDH16 | c.1686del p.K563Sfs*22 | Frame Shift Del (DEL) | VAF 16/75 reads (21%) | catalogued as rs776664434; called by mutect2, pindel, varscan2
- CEP89 | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 48/121 reads (40%) | catalogued as COSV59861879; called by muse, mutect2, varscan2
- CFAP46 | c.5899G>T p.A1967S | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.273); catalogued as COSV54148771, COSV99584208; called by muse, mutect2, varscan2
- CRB1 | c.3102G>A p.W1034* | Nonsense Mutation (SNP) | VAF 10/116 reads (9%) | catalogued as COSV66328589; called by muse, mutect2
- CSMD3 | c.7242A>C p.E2414D (on ENST00000297405 / NM_001363185.1; = p.E2310D on NM_052900.3) | Missense Mutation (SNP) | VAF 82/285 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.901); catalogued as COSV52096739; called by muse, mutect2, varscan2
- CTPS1 | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV101009462, COSV65451704; called by muse, mutect2, varscan2
- CYP1A2 | c.1447G>A p.V483M | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.876); catalogued as rs143028942; called by muse, mutect2, varscan2
- CYP2A7 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs752929206, COSV52496919; called by muse, mutect2, varscan2
- DCUN1D5 | c.487A>G p.K163E | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.842); catalogued as COSV52783741; called by muse, mutect2, varscan2
- DHRS4L2 | c.548A>G p.N183S | Missense Mutation (SNP) | VAF 98/242 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV58728381; called by muse, mutect2
- DHX37 | c.109A>T p.K37* | Nonsense Mutation (SNP) | VAF 80/204 reads (39%) | catalogued as COSV58131602; called by muse, mutect2, varscan2
- DIAPH3 | c.1361+1G>A p.X454_splice (on ENST00000400324 / NM_001042517.2; = p.X191_splice on NM_030932.3) | Splice Site (SNP) | VAF 11/139 reads (8%) | catalogued as rs775635160, COSV57364600; called by muse, mutect2
- DOK2 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 6/143 reads (4%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs867550583, COSV52387505; called by muse, mutect2
- DOP1A | c.2501G>A p.S834N | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV52706582; called by muse, mutect2
- DSC3 | c.2411G>A p.C804Y | Missense Mutation (SNP) | VAF 23/200 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as COSV64571551; called by muse, mutect2, varscan2
- DUOX2 | c.1891C>A p.Q631K | Missense Mutation (SNP) | VAF 117/332 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV66530471; called by muse, mutect2, varscan2
- EIF5A | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV59746816; called by muse, mutect2, varscan2
- EPHA4 | c.980-1G>T p.X327_splice | Splice Site (SNP) | VAF 29/170 reads (17%) | catalogued as COSV56026019; called by muse, mutect2, varscan2
- EXOC1 | c.1430T>C p.L477P | Missense Mutation (SNP) | VAF 16/364 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.877); catalogued as COSV62119058; called by muse, mutect2
- FAH | c.942A>G p.I314M | Missense Mutation (SNP) | VAF 29/215 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV55720001; called by muse, mutect2, varscan2
- FAM83D | c.1000C>A p.L334M | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); catalogued as COSV54156405; called by muse, mutect2, varscan2
- FAM91A1 | c.17A>T p.E6V | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58235541; called by muse, mutect2, varscan2
- FAT3 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1363753482, COSV53073439, COSV53073692; called by muse, mutect2, varscan2
- FBN1 | c.2708T>A p.I903N | Missense Mutation (SNP) | VAF 89/361 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as COSV57308709; called by muse, mutect2, varscan2
- FN1 | c.5464G>A p.V1822M | Missense Mutation (SNP) | VAF 18/424 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV60546155; called by muse, mutect2
- FOXD4 | c.188T>C p.V63A | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs1238839256, COSV58697973; called by muse, mutect2, varscan2
- GABPB2 | c.680C>T p.T227I | Missense Mutation (SNP) | VAF 46/308 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.116); catalogued as COSV64460448; called by muse, mutect2, varscan2
- GLYR1 | c.1189G>A p.G397R | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58925434; called by muse, mutect2, varscan2
- GNB3 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.584); catalogued as rs781969884, COSV51830840; called by muse, mutect2
- GNPDA2 | c.469A>G p.T157A | Missense Mutation (SNP) | VAF 49/213 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.886); catalogued as rs1267927997, COSV54945947; called by muse, mutect2, varscan2
- GRIK5 | c.1174T>C p.Y392H | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.01); catalogued as COSV53474425; called by muse, mutect2, varscan2
- HHIPL2 | c.1166G>A p.G389D | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV58563086; called by muse, mutect2
- HID1 | c.2212G>A p.V738M | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60912097; called by muse, mutect2, varscan2
- HOMER2 | c.538G>A p.V180M (on ENST00000304231 / NM_199330.3; = p.V169M on NM_004839.4) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.657); catalogued as COSV58484193; called by muse, mutect2
- HSPB11 | c.262T>C p.W88R | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV52040222; called by muse, mutect2
- IFT52 | c.71G>A p.G24D | Missense Mutation (SNP) | VAF 8/218 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV65974402; called by muse, mutect2
- IFT81 | c.1651A>T p.R551* | Nonsense Mutation (SNP) | VAF 38/98 reads (39%) | catalogued as COSV54360403; called by muse, mutect2, varscan2
- IGLV7-46 | c.214A>G p.T72A | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.068); catalogued as rs1230071626; called by muse, mutect2, varscan2
- IRAG1 | c.2532G>A p.M844I | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.087); catalogued as COSV70209821; called by muse, mutect2
- IRF7 | c.1492G>A p.A498T (on ENST00000397566; = p.A485T on NM_001572.5) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs772836644, COSV52750784; called by muse, mutect2, varscan2
- ITIH4 | c.1780A>G p.T594A | Missense Mutation (SNP) | VAF 10/163 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV56571181, COSV56578315; called by muse, mutect2
- KANK4 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 79/184 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376267940; called by muse, mutect2, varscan2
- KCNH8 | c.1249A>T p.I417F | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.396); catalogued as COSV104408018, COSV60456001; called by muse, mutect2, varscan2
- KDM5C | c.1771G>A p.G591R | Missense Mutation (SNP) | VAF 40/206 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV64762637; called by muse, mutect2, varscan2
- KIF1A | c.2951A>G p.D984G | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs550429072, COSV57482159; called by muse, mutect2
- KIF3C | c.869C>T p.A290V | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53097516; called by muse, mutect2, varscan2
- KL | c.2011C>T p.R671* | Nonsense Mutation (SNP) | VAF 12/30 reads (40%) | catalogued as rs1384221025, COSV66307765; called by muse, mutect2, varscan2
- KMT2C | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 22/372 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51281968; called by muse, mutect2
- LAMTOR3 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56951878; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 31/289 reads (11%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LEPROTL1 | c.316A>G p.N106D | Missense Mutation (SNP) | VAF 112/401 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as rs1468672630, COSV58304266; called by muse, varscan2
- LONRF2 | c.2212C>T p.R738C | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs377243552, COSV66542067; called by muse, mutect2, varscan2
- LRAT | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60476391; called by muse, mutect2, varscan2
- LRP1B | c.4279C>T p.P1427S | Missense Mutation (SNP) | VAF 11/270 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV101259958, COSV67184228; called by muse, mutect2
- LRRC8E | c.334C>T p.H112Y | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as COSV60716856; called by muse, mutect2, varscan2
- MACROH2A2 | c.950G>A p.G317D | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57158507; called by muse, mutect2, varscan2
- MAD1L1 | c.1667G>A p.R556H | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs755012008, COSV56226072; called by muse, mutect2, varscan2
- MCM10 | c.2155del p.R719Gfs*17 (on ENST00000484800 / NM_182751.3; = p.R718Gfs*17 on NM_018518.5) | Frame Shift Del (DEL) | VAF 46/280 reads (16%) | catalogued as rs1310004144; called by mutect2, varscan2
- MCRS1 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 4/40 reads (10%) | catalogued as rs766260207, COSV59458176; called by mutect2, varscan2
- MGRN1 | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52148021; called by muse, mutect2, varscan2
- MN1 | c.129del p.P45Lfs*8 | Frame Shift Del (DEL) | VAF 7/64 reads (11%) | catalogued as COSV56556167; called by mutect2, pindel, varscan2
- MON1A | c.1036G>A p.G346S | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.373); catalogued as rs138516377; called by muse, mutect2, varscan2
- MYH1 | c.2221G>A p.D741N | Missense Mutation (SNP) | VAF 88/194 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs756226304, COSV56843296; called by muse, mutect2, varscan2
- MYPN | c.2398T>C p.S800P | Missense Mutation (SNP) | VAF 125/312 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV62731432; called by muse, mutect2, varscan2
- NCF4 | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs546311292, COSV50620222; called by muse, mutect2, varscan2
- NEK10 | c.2420G>A p.R807Q | Missense Mutation (SNP) | VAF 59/328 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.209); catalogued as rs1490042557, COSV55354780; called by muse, mutect2, varscan2
- NFATC1 | c.2032G>A p.V678I | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.32); catalogued as rs753211496, COSV53694701; called by muse, mutect2
- NLRP9 | c.23A>G p.D8G | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.766); catalogued as rs762789817, COSV60459261, COSV60459405; called by muse, mutect2, varscan2
- NOP58 | c.286G>T p.G96W | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV51895485; called by muse, mutect2, varscan2
- NPRL2 | c.854A>G p.Y285C | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51599893; called by muse, mutect2
- NRIP2 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs555682970, COSV61701054; called by muse, mutect2, varscan2
- NSD3 | c.3460C>T p.R1154W | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs1387874215, COSV57666735; called by muse, mutect2
- OCA2 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1429075390, COSV62337912; called by muse, mutect2, varscan2
- ONECUT2 | c.538C>T p.H180Y | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.775); catalogued as COSV72203226; called by muse, mutect2, varscan2
- OPHN1 | c.1278T>C p.D426= | Splice Region (SNP) | VAF 31/115 reads (27%) | catalogued as COSV62780103; called by muse, mutect2, varscan2
- OR9Q1 | c.269C>A p.A90E | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.157); catalogued as COSV59036393; called by muse, mutect2, varscan2
- OSBPL10 | c.676G>T p.A226S | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.141); catalogued as COSV67335881; called by muse, mutect2, varscan2
- OTUD7B | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 43/273 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587685362, COSV64914953; called by muse, mutect2, varscan2
- PCDHA3 | c.1931G>A p.R644H | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.082); catalogued as COSV63538662; called by muse, mutect2
- PCDHGA4 | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV53894994; called by muse, mutect2, varscan2
- PDE4DIP | c.6748C>T p.L2250F | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV57673378; called by muse, mutect2
- PDYN | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1004881058, CM132457, COSV54100668; called by muse, mutect2
- PEMT | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376787997; called by muse, mutect2, varscan2
- PIK3CB | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100006173, COSV56683125, COSV56690507; called by muse, mutect2, varscan2
- PIK3R1 | c.2114A>G p.Q705R (on ENST00000521381 / NM_181523.3; = p.Q435R on NM_181504.4) | Missense Mutation (SNP) | VAF 40/208 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57123253; called by muse, mutect2, varscan2
- PIK3R4 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 60/243 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63238971; called by muse, mutect2, varscan2
- PJA2 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 100/242 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs747933906, COSV63271560; called by muse, mutect2, varscan2
- PLAAT4 | c.483dup p.A162Sfs*55 | Frame Shift Ins (INS) | VAF 28/92 reads (30%) | catalogued as rs745860467; called by mutect2, varscan2
- PLCG1 | c.2239T>C p.Y747H | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54814953; called by muse, mutect2, varscan2
- PLXNA4 | c.1646G>A p.R549H | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as rs190791576, COSV58103413; called by muse, mutect2, varscan2
- PLXNB2 | c.2746C>A p.H916N | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV63779991; called by muse, mutect2
- PMPCA | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 58/496 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.043); catalogued as COSV53740562; called by muse, mutect2, varscan2
- POLD1 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs372299975; called by muse, mutect2, varscan2
- PPP1R7 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 13/160 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52147210; called by muse, mutect2
- PRSS8 | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 6/141 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as COSV54894980; called by muse, mutect2
- PSMB1 | c.250G>A p.G84S | Missense Mutation (SNP) | VAF 40/230 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1416252126, COSV51529853; called by muse, mutect2, varscan2
- RAD23A | c.813+1G>C p.X271_splice | Splice Site (SNP) | VAF 8/30 reads (27%) | catalogued as COSV57117144; called by muse, mutect2, varscan2
- RAPGEF1 | c.1324G>A p.G442R | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.084); catalogued as rs1289062746, COSV64697445; called by muse, mutect2, varscan2
- RB1CC1 | c.3986A>G p.Q1329R | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV50242968; called by muse, mutect2
- RBBP8 | c.1071del p.K357Nfs*3 | Frame Shift Del (DEL) | VAF 22/166 reads (13%) | catalogued as rs754547584, COSV59093143; ClinVar: uncertain significance; called by mutect2, varscan2
- RBM11 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 24/273 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs200021740, COSV68747920; called by muse, mutect2
- RC3H1 | c.100G>T p.G34C | Missense Mutation (SNP) | VAF 16/302 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51197783; called by muse, mutect2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 15/100 reads (15%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 26/108 reads (24%) | catalogued as rs755128667, COSV68457540; called by pindel, varscan2
- RNF43 | c.1070A>G p.Y357C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV68456817; called by muse, mutect2
- ROBO2 | c.1841G>A p.R614H | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1196957436, COSV59895199; called by muse, mutect2, varscan2
- RPGRIP1 | c.3354G>A p.M1118I | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV52844329, COSV52849687; called by mutect2, varscan2
- RPL23 | c.172G>T p.G58C | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55559474; called by muse, mutect2
- RTL3 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.242); catalogued as COSV58183019; called by muse, mutect2, varscan2
- RXRA | c.331del p.L111Wfs*57 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | catalogued as COSV62684236; called by mutect2, varscan2
- RYR1 | c.10802C>T p.A3601V | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.45); catalogued as rs764847097, COSV62088117; called by muse, mutect2, varscan2
- SAMD9 | c.3847A>G p.N1283D | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.307); catalogued as COSV66072864; called by muse, mutect2, varscan2
- SEC23IP | c.2965C>T p.R989* | Nonsense Mutation (SNP) | VAF 10/242 reads (4%) | catalogued as rs904414734, COSV64830651; called by muse, mutect2
- SGSM3 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs138251871; called by muse, mutect2
- SHPK | c.495-1G>A p.X165_splice | Splice Site (SNP) | VAF 11/94 reads (12%) | catalogued as COSV56648059; called by muse, mutect2, varscan2
- SLC16A2 | c.439G>A p.G147R | Missense Mutation (SNP) | VAF 76/193 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as CM090716, COSV52082451, COSV52088806; called by muse, mutect2, varscan2
- SLC17A1 | c.617-1G>T p.X206_splice | Splice Site (SNP) | VAF 26/172 reads (15%) | catalogued as COSV55077045; called by muse, mutect2, varscan2
- SLC24A1 | c.2917A>G p.M973V | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs201810804; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLCO2A1 | c.1343G>A p.C448Y | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV60483335; called by muse, mutect2, varscan2
- SMYD5 | c.728G>A p.R243Q | Missense Mutation (SNP) | VAF 110/626 reads (18%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.834); catalogued as rs890159443, COSV50264353; called by muse, mutect2, varscan2
- SOX9 | c.1183A>G p.T395A | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV55422031; called by mutect2, varscan2
- SPATA31D1 | c.2245G>A p.A749T | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs200798404; called by muse, mutect2
- SPHKAP | c.2550G>T p.E850D | Missense Mutation (SNP) | VAF 92/292 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV60867944; called by muse, mutect2
- SPTA1 | c.6274C>A p.L2092M | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as COSV63748547; called by muse, mutect2
- SPTA1 | c.3490C>T p.R1164C | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1037395586, COSV63748550; called by muse, mutect2, varscan2
- SPTA1 | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 28/217 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.593); catalogued as COSV63748554; called by muse, mutect2, varscan2
- SRP72 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV61376766; called by muse, mutect2, varscan2
- SVIL | c.2522C>A p.T841K (on ENST00000355867 / NM_021738.3; = p.T415K on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/356 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV63439488; called by muse, mutect2
- SYDE1 | c.1706C>T p.T569I | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.219); catalogued as rs952598796, COSV54617731; called by muse, mutect2, varscan2
- SYNJ2 | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs202038099, COSV62895517; called by muse, mutect2, varscan2
- TBXAS1 | c.765dup p.N256* | Frame Shift Ins (INS) | VAF 30/247 reads (12%) | catalogued as rs1238810672; called by mutect2, pindel, varscan2
- TGFBR3 | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs201034517, COSV53021339; called by muse, mutect2, varscan2
- TGS1 | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 32/194 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV52698114, COSV99485049; called by muse, mutect2, varscan2
- TMCC1 | c.376G>T p.G126C | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.75); catalogued as COSV67872272; called by muse, mutect2, varscan2
- TMEM120A | c.556G>A p.G186S | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); catalogued as rs782345420, COSV58693388; called by muse, mutect2
- TMPRSS11B | c.1141C>T p.L381F | Missense Mutation (SNP) | VAF 108/239 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60291104; called by muse, mutect2, varscan2
- TUBE1 | c.283A>G p.T95A | Missense Mutation (SNP) | VAF 42/330 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV64087786; called by muse, mutect2, varscan2
- TUT1 | c.1928G>A p.R643Q | Missense Mutation (SNP) | VAF 31/216 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs774183454, COSV53468625; called by muse, mutect2, varscan2
- UBAP1 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs752462139, COSV52657202, COSV99903432; called by muse, mutect2, varscan2
- USP42 | c.1828G>A p.E610K | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1330585888, COSV60357557; called by muse, mutect2, varscan2
- VEGFD | c.961C>T p.H321Y | Missense Mutation (SNP) | VAF 111/248 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.085); catalogued as COSV52908802; called by muse, mutect2, varscan2
- VWA8 | c.4409+2T>C p.X1470_splice | Splice Site (SNP) | VAF 64/370 reads (17%) | catalogued as COSV64993757; called by muse, mutect2, varscan2
- WDHD1 | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV62212766, COSV62215834; called by muse, mutect2, varscan2
- WDR19 | c.3607A>G p.R1203G | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1394483779, COSV56461486; called by muse, mutect2, varscan2
- XPOT | c.1198A>G p.M400V | Missense Mutation (SNP) | VAF 49/192 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as rs770607826, COSV60343741; called by muse, mutect2, varscan2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | catalogued as rs779864368; called by mutect2, pindel, varscan2
- ZGLP1 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as COSV67059222; called by muse, mutect2
- ZMYND15 | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs140331305; called by muse, mutect2, varscan2
- ZMYND19 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.145); catalogued as rs867446857, COSV53021219; called by muse, mutect2, varscan2
- ZNF217 | c.2344G>A p.A782T | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs747242932, COSV56593672; called by muse, mutect2, varscan2
- ZNF550 | c.513G>T p.R171S | Missense Mutation (SNP) | VAF 21/264 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV57303487; called by muse, mutect2
- ZNF568 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs371204967; called by muse, mutect2, varscan2
- ANKRD36B | c.2273del p.N758Tfs*12 | Frame Shift Del (DEL) | VAF 14/122 reads (11%) | called by mutect2, varscan2
- ASH1L | c.2908del p.I970Lfs*9 | Frame Shift Del (DEL) | VAF 23/205 reads (11%) | called by mutect2, pindel, varscan2
- ATF7IP | c.959dup p.N320Kfs*4 | Frame Shift Ins (INS) | VAF 18/114 reads (16%) | called by mutect2, varscan2
- BOC | c.340dup p.A114Gfs*26 | Frame Shift Ins (INS) | VAF 4/31 reads (13%) | called by mutect2, pindel
- C3orf20 | c.998del p.P333Rfs*103 | Frame Shift Del (DEL) | VAF 30/162 reads (19%) | called by mutect2, pindel, varscan2
- CRB1 | c.1838del p.L613Wfs*8 | Frame Shift Del (DEL) | VAF 18/190 reads (9%) | called by mutect2, pindel
- DHRS7 | c.642del p.F214Lfs*14 | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | called by mutect2, pindel, varscan2
- DNAJC2 | c.590del p.N197Mfs*8 | Frame Shift Del (DEL) | VAF 24/204 reads (12%) | called by mutect2, varscan2
- EPB41L2 | c.838_839del p.K280Efs*13 | Frame Shift Del (DEL) | VAF 43/136 reads (32%) | called by mutect2, pindel, varscan2
- FXR1 | c.371dup p.N124Kfs*5 | Frame Shift Ins (INS) | VAF 22/138 reads (16%) | called by mutect2, varscan2
- GANAB | c.68del p.L23* | Frame Shift Del (DEL) | VAF 20/190 reads (11%) | called by mutect2, pindel, varscan2
- IGHV3-16 | c.65A>G p.Q22R | Missense Mutation (SNP) | VAF 27/226 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- KLHL17 | c.1751del p.G584Vfs*100 | Frame Shift Del (DEL) | VAF 7/45 reads (16%) | called by mutect2, pindel, varscan2
- LEF1 | c.391_392del p.L131Ffs*10 | Frame Shift Del (DEL) | VAF 85/241 reads (35%) | called by pindel, varscan2
- LHX1 | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- LHX1 | c.910C>T p.Q304* | Nonsense Mutation (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- MYCBP2 | c.6850_6852del p.Q2284del (on ENST00000357337; = p.Q2322del on NM_015057.5) | In Frame Del (DEL) | VAF 35/344 reads (10%) | called by pindel, varscan2
- NUP35 | c.933del p.D312Mfs*26 | Frame Shift Del (DEL) | VAF 38/227 reads (17%) | called by mutect2, pindel, varscan2
- OR52K2 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 10/302 reads (3%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.559); called by muse, mutect2
- PIGW | c.1013A>G p.K338R | Missense Mutation (SNP) | VAF 61/162 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- POLR2A | c.2518G>A p.A840T | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PTEN | c.264_273del p.Y88* | Frame Shift Del (DEL) | VAF 93/273 reads (34%) | called by mutect2, pindel, varscan2
- RAB1B | c.322_349del p.R108Sfs*47 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | called by mutect2, pindel, varscan2
- SHD | c.356del p.P119Rfs*15 | Frame Shift Del (DEL) | VAF 18/136 reads (13%) | called by mutect2, pindel, varscan2
- TASOR | c.1686del p.F562Lfs*21 (on ENST00000355628 / NM_001365636.2; = p.F166Lfs*21 on NM_015224.3) | Frame Shift Del (DEL) | VAF 10/95 reads (11%) | called by mutect2, pindel, varscan2
- THBS2 | c.1251del p.S419Pfs*9 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by pindel, varscan2
- TLE1 | c.1725del p.A576Pfs*33 | Frame Shift Del (DEL) | VAF 20/57 reads (35%) | called by mutect2, pindel, varscan2
- UFSP2 | c.623del p.N208Ifs*3 | Frame Shift Del (DEL) | VAF 38/187 reads (20%) | called by mutect2, varscan2
- YLPM1 | c.1907dup p.G637Wfs*31 | Frame Shift Ins (INS) | VAF 24/203 reads (12%) | called by mutect2, pindel, varscan2
- ZNF506 | c.345del p.G116Afs*5 | Frame Shift Del (DEL) | VAF 26/247 reads (11%) | called by mutect2, pindel, varscan2
- ACTN3 | c.753C>A p.A251= | Silent (SNP) | VAF 25/121 reads (21%) | catalogued as COSV72207526; called by muse, mutect2, varscan2
- ARHGEF10L | c.294C>T p.D98= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs370847469; called by muse, mutect2, varscan2
- ARHGEF40 | c.1798C>T p.L600= | Silent (SNP) | VAF 6/101 reads (6%) | catalogued as COSV53878076; called by muse, mutect2
- ASAH2 | c.798G>A p.P266= | Silent (SNP) | VAF 114/558 reads (20%) | catalogued as rs143842851, COSV61482711; called by muse, mutect2, varscan2
- ATXN7 | c.1635C>T p.C545= | Silent (SNP) | VAF 47/212 reads (22%) | catalogued as rs768768828, COSV55747889; called by muse, mutect2, varscan2
- CDH18 | c.2223G>A p.E741= | Silent (SNP) | VAF 19/315 reads (6%) | catalogued as COSV56899657, COSV56908715; called by muse, mutect2
- CDHR2 | c.2895G>A p.L965= | Silent (SNP) | VAF 7/113 reads (6%) | catalogued as rs887048129, COSV56134387; called by muse, mutect2
- CHAC2 | c.399T>C p.N133= | Silent (SNP) | VAF 15/324 reads (5%) | catalogued as COSV54857583; called by muse, mutect2
- CHRNG | c.1179G>A p.L393= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as COSV67315207; called by muse, mutect2
- CLIC6 | c.1533G>A p.L511= (on ENST00000360731 / NM_001317009.2; = p.L493= on NM_053277.3) | Silent (SNP) | VAF 88/231 reads (38%) | catalogued as COSV100659346, COSV62447041; called by muse, mutect2, varscan2
- CLUH | c.699C>T p.H233= (on ENST00000435359; = p.H271= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs529857879, COSV70927627; called by muse, mutect2, varscan2
- COMMD4 | c.25C>T p.L9= | Silent (SNP) | VAF 19/129 reads (15%) | catalogued as COSV51190153; called by muse, mutect2, varscan2
- COQ5 | c.120T>G p.A40= | Silent (SNP) | VAF 41/137 reads (30%) | catalogued as COSV56018235; called by muse, mutect2, varscan2
- CYFIP2 | c.3261C>T p.I1087= (on ENST00000616178 / NM_001291722.2; = p.I1062= on NM_014376.4) | Silent (SNP) | VAF 27/54 reads (50%) | catalogued as rs747475869, COSV59027476; called by muse, mutect2, varscan2
- DACT1 | c.1083C>T p.S361= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as rs867054196, COSV60019282; called by muse, mutect2, varscan2
- DAPK1 | c.2499G>T p.T833= | Silent (SNP) | VAF 182/464 reads (39%) | catalogued as COSV63783852; called by muse, mutect2, varscan2
- DEPDC1B | c.1446T>C p.P482= | Silent (SNP) | VAF 20/301 reads (7%) | catalogued as COSV54007926; called by muse, mutect2
- ENPP5 | c.459T>C p.H153= | Silent (SNP) | VAF 16/95 reads (17%) | catalogued as COSV57907991; called by muse, mutect2, varscan2
- FLNB | c.2193C>A p.P731= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV55869598; called by muse, mutect2, varscan2
- GOLGA5 | c.1815G>A p.L605= | Silent (SNP) | VAF 25/127 reads (20%) | catalogued as COSV50831974; called by muse, mutect2, varscan2
- GRK2 | c.1443C>T p.D481= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as rs775188106, COSV57950249; called by muse, mutect2, varscan2
- IFT80 | c.729A>G p.L243= | Silent (SNP) | VAF 75/195 reads (38%) | catalogued as COSV58445200; called by muse, mutect2, varscan2
- LRPPRC | c.3129C>T p.C1043= | Silent (SNP) | VAF 19/526 reads (4%) | catalogued as rs1336865167, COSV53233710; called by muse, mutect2
- MEGF8 | c.2850C>T p.C950= (on ENST00000251268 / NM_001271938.2; = p.C883= on NM_001410.3) | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV52074467; called by muse, mutect2, varscan2
- MMP19 | c.579C>T p.D193= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as rs144496096; called by muse, mutect2, varscan2
- MTR | c.1929T>C p.T643= | Silent (SNP) | VAF 29/236 reads (12%) | catalogued as rs779577547, COSV63963787; called by muse, mutect2, varscan2
- MYH7B | c.1881C>T p.Y627= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as rs535215867, COSV53416302; called by muse, mutect2, varscan2
- NAV2 | c.1602G>A p.T534= (on ENST00000396087 / NM_001244963.2; = p.T511= on NM_145117.5) | Silent (SNP) | VAF 81/200 reads (41%) | catalogued as rs375524165; called by muse, mutect2, varscan2
- OR2T8 | c.921G>T p.V307= | Silent (SNP) | VAF 12/365 reads (3%) | catalogued as COSV60661297; called by muse, mutect2
- PCDHA6 | c.381C>T p.N127= | Silent (SNP) | VAF 20/143 reads (14%) | catalogued as rs1554131328, COSV65349082; called by muse, mutect2, varscan2
- POLR3A | c.3717C>T p.H1239= | Silent (SNP) | VAF 72/167 reads (43%) | catalogued as rs369164731; called by muse, mutect2, varscan2
- PRDM9 | c.1758G>T p.G586= | Silent (SNP) | VAF 35/107 reads (33%) | catalogued as COSV57002087, COSV57005766; called by muse, mutect2, varscan2
- PRKCI | c.1560G>C p.P520= | Silent (SNP) | VAF 76/207 reads (37%) | catalogued as COSV55516545; called by muse, mutect2, varscan2
- QSOX1 | c.735T>C p.S245= | Silent (SNP) | VAF 18/178 reads (10%) | catalogued as COSV62579513; called by muse, mutect2
- RBM19 | c.1785G>A p.P595= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs144311475; called by muse, mutect2, varscan2
- RDH8 | c.567C>T p.L189= (on ENST00000651512; = p.L169= on NM_015725.4) | Silent (SNP) | VAF 71/162 reads (44%) | catalogued as rs763537587, COSV50673895; called by muse, mutect2, varscan2
- SEC14L5 | c.642C>T p.P214= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs752522223, COSV52036099; called by muse, mutect2
- SNX33 | c.1119C>T p.D373= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as rs1340984686, COSV57912647; called by muse, mutect2, varscan2
- SPATA31D1 | c.2841A>G p.S947= | Silent (SNP) | VAF 14/172 reads (8%) | catalogued as COSV61192555; called by muse, mutect2
- STT3A | c.480A>T p.R160= | Silent (SNP) | VAF 16/315 reads (5%) | catalogued as COSV67064054; called by muse, mutect2
- TEX47 | c.312C>T p.S104= | Silent (SNP) | VAF 70/176 reads (40%) | catalogued as rs146825913; called by muse, mutect2, varscan2
- TOP1MT | c.1626G>A p.T542= | Silent (SNP) | VAF 7/118 reads (6%) | catalogued as rs1055385695, COSV61316222; called by muse, mutect2
- UGT1A7 | c.546G>A p.Q182= | Silent (SNP) | VAF 26/533 reads (5%) | catalogued as rs1462405712, COSV60830717; called by muse, mutect2
- UHRF1BP1 | c.3510G>A p.G1170= | Silent (SNP) | VAF 28/216 reads (13%) | catalogued as COSV51952486; called by muse, varscan2
- USF3 | c.4965T>C p.C1655= | Silent (SNP) | VAF 17/198 reads (9%) | catalogued as COSV57069527; called by muse, mutect2
- UTP6 | c.906C>T p.V302= | Silent (SNP) | VAF 24/183 reads (13%) | catalogued as rs532692953, COSV55571325; called by muse, mutect2, varscan2
- ZNF394 | c.1249C>T p.L417= | Silent (SNP) | VAF 36/388 reads (9%) | catalogued as COSV61793383; called by muse, mutect2
- ZNF439 | c.519G>A p.L173= | Silent (SNP) | VAF 27/223 reads (12%) | catalogued as COSV58308360; called by muse, mutect2, varscan2
- ZNF500 | c.1047C>T p.G349= | Silent (SNP) | VAF 14/136 reads (10%) | catalogued as rs143816002; called by muse, mutect2, varscan2
- ZNF513 | c.771G>A p.Q257= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV52006241; called by muse, mutect2, varscan2
- ZNF721 | c.2259C>A p.S753= (on ENST00000338977; = p.S765= on NM_133474.4) | Silent (SNP) | VAF 18/108 reads (17%) | catalogued as COSV59088793, COSV59097027; called by muse, mutect2, varscan2
- KCNU1 | c.2010-16994A>G | Intron (SNP) | VAF 23/270 reads (9%) | catalogued as rs1387061212; called by muse, mutect2
- MIR541 | n.61C>A | RNA (SNP) | VAF 31/97 reads (32%) | called by muse, mutect2, varscan2
- MTMR1 | c.1656+196del | Intron (DEL) | VAF 6/26 reads (23%) | called by mutect2, pindel, varscan2
